Surgical pathology report (de-identified scan), TCGA case TCGA-24-1846, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1846-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

***** CORRECTED REPORT *****

FINAL

DIAGNOSIS:

OVARY AND FALLOPIAN TUBE, RIGHT, MODIFIED POSTERIOR EXENTERATION

- OVARIAN, PERIOVARIAN AND PERITUBAL HIGH GRADE SEROUS CARCINOMA (4.5 CM)

OVARY AND FALLOPIAN TUBE, LEFT, MODIFIED POSTERIOR EXENTERATION

- OVARIAN, PERIOVARIAN AND PERITUBAL HIGH GRADE SEROUS CARCINOMA (3.8 CM)
- FALLOPIAN TUBE EPITHELIUM FREE OF CARCINOMA
- PARATUBAL CYST

SOFT TISSUE, POSTERIOR CUL-DE-SAC, MODIFIED POSTERIOR EXENTERATION

- HIGH GRADE SEROUS CARCINOMA (7.5 CM)
- LYMPHVASCULAR SPACE INVASION IS PRESENT

UTERUS, MODIFIED POSTERIOR EXENTERATION

- HIGH GRADE SEROUS CARCINOMA INVOLVING ANTERIOR AND POSTERIOR CERVICAL AND LOWER UTERINE SEGMENT SEROSA AND SUBJACENT STROMA AND UTERINE SEROSA
- LYMPHVASCULAR SPACE INVASION INVOLVING CERVICAL STROMA AND MYOMETRIUM
- WEAKLY PROLIFERATIVE ENDOMETRIUM
- ADENOMYOSIS
- CERVICAL SQUAMOUS AND GLANDULAR MUCOSA WITH NO EVIDENCE OF DYSPLASIA OR MALIGNANCY

LARGE INTESTINE, RECTOSIGMOID COLON, MODIFIED POSTERIOR EXENTERATION

- HIGH GRADE SEROUS CARCINOMA INVOLVING SUBSEROUSAL TISSUE AND MUSCULARIS PROPRIA, WITH SUBMUCOSAL AND MUSCULARIS MUCOSAE LYMPHVASCULAR SPACE INVASION
- SURGICAL LATERAL MARGINS, NO EVIDENCE OF MALIGNANCY

OMENTUM, BIOPSY (INCLUDING FS1)

- HIGH GRADE SEROUS CARCINOMA

LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION

- METASTATIC HIGH GRADE SEROUS CARCINOMA IN ONE LYMPH NODE (1/1) WITH FOCAL EXTRACAPSULAR EXTENSION (LESS 1 MM)
- LYMPHOVASCULAR SPACE INVASION PRESENT IN PERINODAL SOFT TISSUE

SOFT TISSUE, "BLADDER PERITONEUM," EXCISION

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

TCGA-24-1846

- HIGH GRADE SEROUS CARCINOMA

APPENDIX, EXCISION

- SEROSAL HIGH GRADE SEROUS CARCINOMA
- APPENDICEAL MUCOSA AND PROXIMAL MARGIN WITH NO EVIDENCE OF MALIGNANCY

OMENTUM, GASTROCOLIC, EXCISION

- HIGH GRADE SEROUS CARCINOMA (LARGEST 10 CM)

SMALL INTESTINE, "MECKEL'S," EXCISION

- BENIGN SMALL INTESTINE MUCOSA, CONSISTENT WITH MECKEL'S DIVERTICULUM
- ACUTE SEROSITIS

LARGE INTESTINE, ANASTOMOTIC DONUT, EXCISION

- NO EVIDENCE OF MALIGNANCY

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Called to pick up 'omentum biopsy' consisting of an irregular shaped piece of red-tan to tan-white tissue measuring 7 x 2.5 x 2 cm. Sectioning of the tissue shows smooth, firm, off-white cut surfaces. Two representative sections are frozen as FS1. Remainder for permanents,"

FS1: Omentum, biopsy

- "Poorly differentiated carcinoma, consistent with high grade serous carcinoma,"

Microscopic Description and Comment:

The carcinoma involves the right and left adnexal regions. In the left, a fragment of fallopian tube is identified, while it is not possible to accurately identify the right fallopian tube.

History:

The patient is a with a pelvic mass in the posterior cul-de-sac and an elevated CA-125.

Specimen(s) Received:

- A: OMENTUM
- B: RIGHT EXTERNAL ILIAC LYMPH NODE
- C: MODIFIED POSTERIOR EXENTERATION
- D: BLADDER PERITONEUM
- E: APPENDIX
- F: GASTRO-COLIC OMENTUM
- G: MECKEL'S
- H: ANASTOMOTIC DONUTS

Gross Description:

The specimens are received in eight formalin-filled containers, each labeled The first container is

[page 3 of 4]
TCGA-24-1846

labeled "omental biopsy, FS1/X." It holds fragments of firm, off-white to yellow tissue and a white cassette labeled "FS1." The cassette contains two pieces of yellow-white tissue, measuring 2.4 x 1.1 x 0.3 cm and 1 x 1 x 0.3 cm. Labeled A1 (FS1). The remaining tissue is comprised of multinodular, light yellow, firm material consistent with omental caking by tumor.

The second container is labeled "right external iliac lymph node." It holds a piece of firm, tan-brown lymph node measuring 2.5 x 1.2 x 0.5 cm with attached yellow fibrofatty tissue. Sections show a white discoloration within the tan-brown lymph node. The putative implant measures 1.8 cm.

The third container is labeled "modified posterior exenteration." It holds rectosigmoid colon, cul-de-sac mass, and uterus with bilateral tubes and ovaries, en bloc. The specimen weighs 950 grams and the soft tissue margins are inked black. The rectum measures 15 cm in length. The uterus measures 9 cm from fundus to os, 4 cm from anterior to posterior and 5 cm from cornu to cornu. The external os is oval and patent. The exocervix is smooth, white and shiny. The endometrium and endocervix show smooth, tan-brown surface with no gross tumor. The myometrium measures a maximum of 19 mm in thickness and is also unremarkable, except for the posterior distortion by the cul-de-sac tumor. The specimen also shows a 7.5 x 6.5 x 6 cm cystic and solid mass with tan-yellow, fleshy cut surfaces that lies between the rectosigmoid and posterior cervix and lower uterine segment in the posterior cul-de-sac. A cystic area measuring 2.5 x 2.7 x 2.8 cm is identified immediately deep to the rectosigmoid, 5.5 cm from the distal margin. The colon is opened to show tan-brown mucosa with no gross abnormality with tumor involving the serosa and muscularis wall. The posterior cervix and lower uterine segment are indented by a solid portion of the tumor, but gross invasion into the substance of the uterus is not identified. There is an anterior implant of firm, white-grey tumor abutting the anterior serosal surface of the lower uterine segment measuring 1 cm in diameter and 7 cm in length. The ovaries are involved in matted tumor aggregating to 4.5 cm on the right and 3.8 cm on the left. The left ovary and tube contain a cyst measuring 2.5 x 2.5 x 2.5 cm. Sections of the cyst show clear, colorless fluid and a cyst wall measuring <0.1 cm in diameter. The left ovary measures 2.5 x 1.5 x 2 cm and the cut surface is firm, white-yellow, similar to the cut surface of the tumor implants involving the adnexa and posterior cul-de-sac. The fallopian tubes are essentially obliterated by the tumor masses. Gross photograph taken. Labeled C1, proximal rectum margin; C2, distal rectum margin; C3, radial section of tumor at inferior inked surface; C4, rectum with underlying cystic portion of tumor; C5, more proximal portion of rectum; C6, posterior cervix; C7, posterior lower uterine segment with tumor; C8, posterior endomyometrium; C9, anterior cervix; C10, anterior lower uterine segment with tumor nodule; C11, anterior endomyometrium; C12, left ovary; C13, left adnexal cyst; C14, left adnexal tumor mass; C15 to C17, right adnexal tumor mass; C18, left soft tissue margin; C19 - right soft tissue margin.

The fourth container is labeled "bladder peritoneum." It holds a piece of glistening, tan-pink peritoneum studded with numerous tumor implants. The section measures 15 x 3 x 1 cm. The tumor implants are nearly confluent but generally range from 0.5 to 1.5 cm in greatest dimension.

The fifth container is labeled "appendix." It holds an intact appendix measuring 5 x 0.8 cm. At the tip of the appendix and 1.5 cm from the tip of the appendix there are nodules measuring 0.4 and 0.5 cm. The appendix shows an intact lumen measuring 0.1 to 0.2 cm in diameter. Labeled E1, tip of appendix section with nodule, and proximal cross section;

The sixth container is labeled "gastrocolic omentum." It holds a piece of yellow-tan, fibrofatty omentum measuring 25 x 14 cm. In addition, there are several fragments of yellow-tan, fibrofatty tissue containing tumor implants measuring 1 to 1.5 cm in greatest dimension. There is a caking of the gastrocolic omentum measuring 10 x 4 x 3 cm at one edge. Labeled F1 to F3, tumor implant.

The seventh container is labeled "intestine." It holds a piece of apparent intestine measuring 1.5 x 1 x 0.9 cm, stapled on one end. The staples are removed. The specimen is opened to show a diverticulum with yellow-tan mucosa. No tumor is identified. Labeled G1

The eighth container is labeled "anastomotic donut." It holds two pieces of tan-brown, unremarkable intestinal mucosa invested with staples.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

[page 4 of 4]
II.

SURGICAL PATHOLOGY REPORT

TCGA-24-1846

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 1

The total number of metastatically-involved lymph nodes is 1

Extranodal extension by tumor metastases is present

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed

STAGE GROUPING

T3c/N1/MX

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Corrections

Source: NCI Genomic Data Commons file 9bee0ff4-3714-4857-b082-1aba8bc9a8f6 (TCGA-24-1846.FB12E5B3-1529-4873-90FD-7BA0A78DD9F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).